Gene-level copy-number profile of tumor specimen TCGA-EE-A2MH-06A from TCGA case TCGA-EE-A2MH, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 66.8 years (24,399 days).
Specimen TCGA-EE-A2MH-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.6be12952-6239-4cfe-9f8a-0567da3b653b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2MH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2a9e67e2-ca64-421b-a6a7-331c89ceac2e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 89; copy number 1: 11,001; copy number 2: 44,946; copy number 3: 1,032; copy number 4: 1,937; copy number 5: 5; copy number 6: 21; copy number 7: 204; copy number 8: 18; copy number 9: 115; copy number 10: 12; copy number 11: 114; copy number 12: 110; copy number 13: 7; copy number 14: 7; copy number 15: 16; copy number 16: 45; copy number 17: 35; copy number 18: 75; copy number 20: 10; copy number 21: 11; copy number 22: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A2MH-06A-11D-A191-01): tumor purity 0.43, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 89 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,918,188–22,518,871, 89 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 807 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:49,909,789–53,251,637, 30 genes, copy number 5–13 (within-gene range 2–13): SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1, NPBWR1, AC009800.1, AC009646.1, AC009646.2, OPRK1.
- chr8:57,126,655–57,592,451, 10 genes, copy number 8: RNA5SP266, LINC01606, AC025674.1, AC025674.2, LINC00588, RNU6-596P, AC068075.1, RPL30P10, AC068075.2, AC090796.1.
- chr8:63,136,223–63,234,911, 5 genes, copy number 8: AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P.
- chr8:67,062,417–67,196,778, 1 gene, copy number 7 (within-gene range 2–7): CSPP1.
- chr8:67,133,554–67,849,338, 9 genes, copy number 7: AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6.
- chr8:68,330,955–68,819,023, 2 genes, copy number 6 (within-gene range 3–6): C8orf34, RPS15AP25.
- chr8:69,667,046–69,834,978, 3 genes, copy number 7 (within-gene range 2–7): SLCO5A1, RN7SKP29, AC091047.1.
- chr8:69,987,415–76,308,315, 100 genes, copy number 5–15 (within-gene range 3–15) (broad region; genes not listed).
- chr8:76,681,239–86,478,420, 148 genes, copy number 6–21 (within-gene range 3–21) (broad region; genes not listed).
- chr8:90,592,804–91,040,872, 8 genes, copy number 9 (within-gene range 3–9): LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2.
- chr8:95,039,617–95,156,685, 7 genes, copy number 11: AC068189.2, RNU6-1209P, MIR3150BHG, AC068189.1, MIR3150B, MIR3150A, PLEKHF2.
- chr8:95,206,876–95,269,201, 2 genes, copy number 11: LINC01298, C8orf37.
- chr8:95,947,781–95,993,103, 2 genes, copy number 16: SRSF3P2, AC012339.1.
- chr8:97,644,184–97,730,260, 1 gene, copy number 12 (within-gene range 3–13): MTDH.
- chr8:142,089,827–145,066,685, 169 genes, copy number 7 (broad region; genes not listed).
- chr20:51,386,957–64,313,132, 310 genes, copy number 7–22 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,580. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
